Surgical pathology report (de-identified scan), TCGA case TCGA-61-1916, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1916-02A (Recurrent Tumor).

FINAL DIAGNOSIS:

PART 1: SMALL BOWEL NODULE, EXCISION -
METASTATIC PAPILLARY SEROUS CARCINOMA (see comment).

PART 2: VENTRAL WALL HERNIA SAC, EXCISION -
A. METASTATIC PAPILLARY SEROUS CARCINOMA.
B. ANGIOLYMPHATIC INVASION IDENTIFIED.

PART 3: UMBILICAL HERNIA SAC, EXCISION -
A. METASTATIC PAPILLARY SEROUS CARCINOMA.
B. ANGIOLYMPHATIC INVASION IDENTIFIED.

COMMENT:

The tumor in the current specimens is morphologically similar to the patient's previously diagnosed papillary serous tumor (cross refe

** Report Electronically Signed Out **
By Pathologist:

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

ICD - 0 - 3
carcinoma, serous, papillary 8461/3
Site: peritoneum, nos C48.2
lw
1/24/15

Source: NCI Genomic Data Commons file 293f455f-0ae0-4a35-8066-d0652b27de04 (TCGA-61-1916.C85D2BF7-498B-4E17-9F13-899AC8D6EC88.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).